Gene-level copy-number profile of tumor specimen TCGA-55-A4DG-01A from TCGA case TCGA-55-A4DG, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.3 years (26,044 days).
Specimen TCGA-55-A4DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.0e523d5e-6ce3-42d5-8867-fa4d569600b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-A4DG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/149c451e-ed4b-43f7-be94-116a09cba98b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,752; copy number 2: 11,591; copy number 3: 14,878; copy number 4: 20,001; copy number 5: 3,455; copy number 6: 2,646; copy number 7: 2,532; copy number 8: 1,051; copy number 9: 218; copy number 12: 269; copy number 13: 343; copy number 16: 82.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-A4DG-01A-11D-A24C-01): tumor purity 0.41, ploidy 3.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 912 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,305,580–248,919,946, 218 genes, copy number 9 (broad region; genes not listed).
- chr5:58,198–43,886,628, 694 genes, copy number 12–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
